Somatic mutation profile of tumor specimen 80a970f7-7b36-4450-aff8-0b55dc (aliquot 80a970f7-7b36-4450-aff8-0b55dc_D6_1) from CPTAC case 11BR058, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.5 years (23,937 days).
Specimen 80a970f7-7b36-4450-aff8-0b55dc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 902b5a8b-e564-4f72-b961-1e6d836e782b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 425542b5-a675-4283-8480-ff386a (Blood Derived Normal), aliquot 425542b5-a675-4283-8480-ff386a_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb8fd9c-5161-4c8d-ac83-767f3fcededc

The open-access MAF lists 84 somatic variants for this specimen: 56 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 21, Nonsense Mutation 2, RNA 2, Intron 2, 3'UTR 1, 5'Flank 1, In Frame Ins 1, 5'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 120/652 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV61656634; called by muse, mutect2, varscan2
- AHNAK2 | c.9159G>T p.E3053D | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.85); catalogued as rs1373338522; called by muse, mutect2, varscan2
- ANK2 | c.8867C>T p.S2956F | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV52162370; called by muse, mutect2
- BMS1 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100996803; called by muse, mutect2, varscan2
- BOD1L1 | c.5086G>C p.E1696Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1339320384; called by muse, mutect2, varscan2
- CCDC120 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as rs1557080517; called by muse, mutect2
- CCNT1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as COSV56064151; called by muse, mutect2, varscan2
- CHRAC1 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99636183; called by muse, mutect2, varscan2
- CLCA4 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.443); catalogued as rs201894845; called by muse, mutect2, varscan2
- DENND5B | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1319969407; called by muse, mutect2, varscan2
- FCER2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100689559, COSV60916152; called by muse, mutect2, varscan2
- GCNT1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs368265529, COSV65058001; called by muse, mutect2, varscan2
- GPRIN2 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1555019868; called by muse, mutect2
- HSPA1B | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 29/598 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.823); catalogued as rs762089786; called by muse, mutect2
- ITGAM | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs551470084; called by muse, mutect2, varscan2
- LRRC66 | c.1949C>A p.S650* | Nonsense Mutation (SNP) | VAF 24/236 reads (10%) | catalogued as COSV58633395; called by muse, mutect2, varscan2
- LTBP4 | c.794C>A p.A265E (on ENST00000308370 / NM_001042544.1; = p.A228E on NM_003573.2) | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV52588892; called by muse, mutect2
- NBPF20 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 44/429 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.34); catalogued as rs782788731; called by muse, mutect2, varscan2
- NPTX2 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as rs936955349, COSV55718362; called by muse, mutect2, varscan2
- OPLAH | c.3740C>T p.T1247M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66298667; called by muse, mutect2
- PCNT | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2
- PON1 | c.869A>G p.K290R | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs757515307; called by muse, mutect2, varscan2
- SLC29A1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 70/798 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747786606, COSV57580508; called by muse, mutect2
- SLC2A2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as CM1110763; called by muse, mutect2, varscan2
- TMPRSS13 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs778644730, COSV70625527; called by muse, mutect2
- TNFAIP8L2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs199843185; called by muse, mutect2, varscan2
- ZC3H3 | c.1125C>G p.S375R | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52794148; called by muse, mutect2, varscan2
- A2M | c.1892_1893insAGAAAAGGACCTCACTGGCTTCCT p.P631_G632insEKDLTGFL | In Frame Ins (INS) | VAF 4/33 reads (12%) | called by muse*, mutect2
- ADAMTS16 | c.3347G>T p.R1116M | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ADGRG7 | c.1949T>C p.V650A | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CALML6 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CDC5L | c.2282C>G p.S761C | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBL2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CUL9 | c.1547C>G p.P516R | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CXCR4 | c.945C>A p.H315Q | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DEDD | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 16/373 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2
- DENND5A | c.2873T>G p.I958S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAJC1 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FBXO38 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GHITM | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IARS1 | c.2185A>G p.I729V | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP1 | c.979A>G p.M327V | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KRTAP12-4 | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LINGO3 | c.509_510insTG p.G172Rfs*9 | Frame Shift Ins (INS) | VAF 46/327 reads (14%) | called by muse*, mutect2, varscan2*
- NFXL1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NINL | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- NKPD1 | c.1010G>C p.R337P | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLIG1 | c.410C>A p.A137E | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PHLDB1 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCG2 | c.1360A>G p.K454E | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TRRAP | c.11078C>A p.P3693H (on ENST00000359863 / NM_001244580.1; = p.P3664H on NM_003496.3) | Missense Mutation (SNP) | VAF 130/430 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TSC22D3 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- TTLL5 | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFPM1 | c.487_505+4del p.X163_splice | Splice Site (DEL) | VAF 20/177 reads (11%) | called by mutect2, pindel
- ZNF326 | c.27C>A p.H9Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- ADCY9 | c.2622G>A p.S874= | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as rs1436665952, COSV53576565; called by muse, mutect2, varscan2
- AIMP2 | c.351G>A p.G117= | Silent (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3045G>A p.K1015= | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- CDH6 | c.1026G>A p.V342= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- CFAP46 | c.7551G>A p.L2517= | Silent (SNP) | VAF 77/275 reads (28%) | called by muse, mutect2, varscan2
- CNOT6L | c.460C>T p.L154= (on ENST00000504123 / NM_001286790.2; = p.L149= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- H2AC20 | c.27C>T p.G9= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as rs782745115; called by muse, mutect2
- JUN | c.814A>C p.R272= | Silent (SNP) | VAF 60/546 reads (11%) | called by muse, mutect2, varscan2
- KIAA0895L | c.1158T>C p.C386= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- LGALS1 | c.195C>T p.D65= | Silent (SNP) | VAF 46/223 reads (21%) | catalogued as rs749836349; called by muse, mutect2, varscan2
- LRRC69 | c.591T>C p.D197= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- MCM10 | c.1704G>A p.R568= (on ENST00000484800 / NM_182751.3; = p.R567= on NM_018518.5) | Silent (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- MEP1A | c.1179G>A p.V393= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- OR7G3 | c.606G>A p.V202= | Silent (SNP) | VAF 30/214 reads (14%) | catalogued as COSV59640045; called by muse, mutect2, varscan2
- PCLO | c.13017G>A p.P4339= | Silent (SNP) | VAF 47/388 reads (12%) | catalogued as rs772226753; called by muse, mutect2, varscan2
- PLPPR3 | c.933C>T p.H311= (on ENST00000520876 / NM_001270366.2; = p.H339= on NM_024888.2) | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as rs748738596, COSV62460707; called by muse, mutect2, varscan2
- SEMA5A | c.3075G>C p.L1025= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- SLX4 | c.5424C>T p.F1808= | Silent (SNP) | VAF 85/611 reads (14%) | catalogued as COSV53569235; called by muse, mutect2, varscan2
- TSPYL6 | c.1017C>T p.F339= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as rs867939731, COSV100336586; called by muse, mutect2, varscan2
- ZNF789 | c.714C>T p.F238= | Silent (SNP) | VAF 18/253 reads (7%) | catalogued as COSV58873818; called by muse, mutect2
- ZSCAN31 | c.1161C>G p.L387= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- AC245047.1 | n.140G>T | RNA (SNP) | VAF 49/130 reads (38%) | catalogued as rs372983797; called by muse, varscan2
- FTH1 | chr11:61968460 G>A | 5'Flank (SNP) | VAF 28/242 reads (12%) | called by muse, mutect2, varscan2
- FUS | c.-25C>G | 5'UTR (SNP) | VAF 47/299 reads (16%) | catalogued as rs1293346511; called by muse, mutect2, varscan2
- HOOK2 | c.1600-18G>T | Intron (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2, varscan2
- LSS | c.1989-730C>T | Intron (SNP) | VAF 60/792 reads (8%) | catalogued as rs1286337889, COSV62699869; called by mutect2, varscan2
- PRRT1 | c.*225C>T | 3'UTR (SNP) | VAF 24/164 reads (15%) | catalogued as COSV99278182; called by muse, mutect2, varscan2
- RASA4DP | n.1134G>C | RNA (SNP) | VAF 112/730 reads (15%) | called by muse, mutect2, varscan2
